Somatic mutation profile of tumor specimen 0DFHGE from CCDI case PBBSGA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.6 years (4,984 days).
Specimen 0DFHGE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa0eee71-3c1a-48f7-a0d2-f662e5634f38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFHGF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a3e99db-2418-4ee7-bb88-8465798d2b37

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Splice Site 4, Frame Shift Del 3, Intron 3, Nonsense Mutation 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE2 | c.1602del p.V535Cfs*2 | Frame Shift Del (DEL) | VAF 204/584 reads (35%) | catalogued as COSV59692453; called by mutect2, pindel, varscan2
- BTNL8 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 197/417 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51458108; called by muse, mutect2, varscan2
- C17orf67 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 118/745 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758412594, COSV67374654; called by muse, mutect2, varscan2
- CCDC61 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1035365424; called by muse, mutect2, varscan2
- CCNP | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.15); catalogued as COSV99695733; called by mutect2, varscan2
- COL12A1 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 106/327 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV59399427; called by muse, mutect2, varscan2
- FSIP2 | c.18567G>T p.K6189N | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100555623; called by muse, mutect2
- HCN4 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 173/545 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756293276, COSV56082563; called by muse, mutect2, varscan2
- IRGC | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54984737; called by muse, mutect2
- SPTBN2 | c.5267C>T p.A1756V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754055406, COSV100020464; called by muse, mutect2
- STK31 | c.1133+1G>T p.X378_splice | Splice Site (SNP) | VAF 41/367 reads (11%) | catalogued as COSV63455573; called by muse, mutect2, varscan2
- TOP2B | c.4148A>C p.D1383A (on ENST00000264331 / NM_001330700.2; = p.D1378A on NM_001068.3) | Missense Mutation (SNP) | VAF 103/210 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.142); catalogued as rs369748980, COSV51977121; called by muse, mutect2, varscan2
- ADAMTS12 | c.3499G>T p.E1167* | Nonsense Mutation (SNP) | VAF 95/322 reads (30%) | called by muse, mutect2, varscan2
- ANKRD33B | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- C5 | c.3039G>C p.M1013I | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CASR | c.2018del p.S673Tfs*27 (on ENST00000490131; = p.S750Tfs*27 on NM_000388.4) | Frame Shift Del (DEL) | VAF 58/219 reads (26%) | called by mutect2, pindel, varscan2
- COL6A6 | c.4726G>C p.G1576R | Missense Mutation (SNP) | VAF 141/476 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT14 | c.1501-1G>T p.X501_splice | Splice Site (SNP) | VAF 84/446 reads (19%) | called by mutect2, varscan2
- GFER | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IFT140 | c.3494G>A p.S1165N | Missense Mutation (SNP) | VAF 130/435 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IL5 | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MOCOS | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MST1L | n.215+2T>G | Splice Site (SNP) | VAF 69/504 reads (14%) | called by muse, mutect2, varscan2
- MUC22 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 165/568 reads (29%) | SIFT tolerated (0.36); called by muse, mutect2, varscan2
- NEU1 | c.730del p.S244Vfs*59 | Frame Shift Del (DEL) | VAF 105/427 reads (25%) | called by mutect2, pindel, varscan2
- PDLIM5 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 169/657 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SDK1 | c.568A>T p.M190L | Missense Mutation (SNP) | VAF 99/612 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SI | c.4000-1G>A p.X1334_splice | Splice Site (SNP) | VAF 107/353 reads (30%) | called by muse, mutect2, varscan2
- SLC26A9 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SNX17 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 114/655 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- UTP25 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ABCA5 | c.3186A>G p.P1062= | Silent (SNP) | VAF 146/460 reads (32%) | catalogued as rs1181965961; called by muse, mutect2, varscan2
- ABLIM1 | c.1404A>C p.P468= | Silent (SNP) | VAF 22/447 reads (5%) | called by muse, mutect2
- ANKRD11 | c.3738C>T p.H1246= | Silent (SNP) | VAF 197/591 reads (33%) | catalogued as rs541050910; called by muse, mutect2, varscan2
- ATP6V0D1 | c.345C>T p.G115= | Silent (SNP) | VAF 49/331 reads (15%) | called by muse, mutect2, varscan2
- CALU | c.705G>A p.E235= | Silent (SNP) | VAF 208/688 reads (30%) | called by muse, mutect2, varscan2
- CNPY2 | c.363A>G p.Q121= | Silent (SNP) | VAF 85/434 reads (20%) | catalogued as COSV99836601; called by muse, mutect2, varscan2
- EHHADH | c.531G>T p.P177= | Silent (SNP) | VAF 112/364 reads (31%) | catalogued as rs148411037; called by muse, mutect2, varscan2
- LILRA5 | c.783C>T p.Y261= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as rs201689439, COSV56642880; called by muse, mutect2
- LRRD1 | c.255T>C p.L85= | Silent (SNP) | VAF 115/612 reads (19%) | called by muse, mutect2, varscan2
- MUC22 | c.1266A>T p.T422= | Silent (SNP) | VAF 148/508 reads (29%) | called by mutect2, varscan2
- PRLR | c.1224T>A p.A408= | Silent (SNP) | VAF 61/248 reads (25%) | called by muse, mutect2, varscan2
- SVEP1 | c.4683A>T p.G1561= | Silent (SNP) | VAF 122/364 reads (34%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.*55A>C | 3'UTR (SNP) | VAF 37/214 reads (17%) | called by muse, mutect2
- PIGG | c.2070-81C>T | Intron (SNP) | VAF 61/120 reads (51%) | called by muse, mutect2, varscan2
- SCN8A | c.706+185dup | Intron (INS) | VAF 102/441 reads (23%) | called by mutect2, pindel, varscan2
- SLC6A12 | c.712-86G>T | Intron (SNP) | VAF 32/125 reads (26%) | catalogued as COSV62883692; called by muse, mutect2, varscan2
- SSPOP | n.6264C>A | RNA (SNP) | VAF 163/1016 reads (16%) | called by muse, mutect2, varscan2
